Gene-level copy-number profile of tumor specimen TCGA-GV-A3JV-01A from TCGA case TCGA-GV-A3JV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.4 years (24,243 days).
Specimen TCGA-GV-A3JV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ed95e7ad-789a-473d-a06f-1138f58fa14c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A3JV-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/699d7e3b-d42d-4ac2-a387-bb93c8942312

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 51; copy number 2: 9,883; copy number 3: 31,051; copy number 4: 12,912; copy number 5: 3,230; copy number 6: 110; copy number 7: 2,421; copy number 9: 54; copy number 17: 40; copy number 29: 11; copy number 35: 19; copy number 37: 2; copy number 38: 5; copy number 41: 4; copy number 44: 4; copy number 46: 7; copy number 48: 1; copy number 51: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A3JV-01A-11D-A21Y-01): tumor purity 0.66, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,577 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:12,004,388–12,434,356, 7 genes, copy number 46: SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1.
- chr3:12,897,043–13,283,281, 2 genes, copy number 35: IQSEC1, AC069271.1.
- chr3:13,476,982–13,880,071, 5 genes, copy number 38: HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A.
- chr3:14,920,347–15,099,163, 4 genes, copy number 44 (within-gene range 5–44): FGD5-AS1, NR2C2, MRPS25, RBSN.
- chr3:16,174,680–16,231,992, 1 gene, copy number 48: GALNT15.
- chr3:169,613,510–170,396,835, 30 genes, copy number 9–51: AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL.
- chr6:134,343,307–135,219,173, 17 genes, copy number 35: LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1.
- chr8:2,935,353–4,994,972, 1 gene, copy number 7 (within-gene range 6–7): CSMD1.
- chr8:4,317,388–145,066,685, 2,420 genes, copy number 7 (broad region; genes not listed).
- chr11:69,641,156–69,675,416, 2 genes, copy number 37: CCND1, LTO1.
- chr11:70,372,246–70,436,584, 2 genes, copy number 41 (within-gene range 3–41): AP000487.1, CTTN.
- chr11:70,477,277–70,604,859, 2 genes, copy number 41: AP001271.1, AP001271.2.
- chr12:19,107,854–19,720,801, 12 genes, copy number 17 (within-gene range 3–17): MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1.
- chr12:46,970,504–47,485,722, 16 genes, copy number 17: AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1.
- chr12:58,087,892–59,064,238, 11 genes, copy number 29 (within-gene range 3–29): LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr12:114,353,911–114,771,851, 12 genes, copy number 17: TBX5, TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2.
- chr14:70,722,526–71,321,882, 16 genes, copy number 9 (within-gene range 3–9): MAP3K9, AC004816.1, AC004816.2, AC004825.1, AC004825.2, PCNX1, AC004825.3, AC005230.1, GTF3AP2, PTTG4P, AC004817.3, AC004817.5, AC004817.2, AC004817.1, AC004817.4, AC005476.2.
- chr14:71,330,342–71,448,958, 3 genes, copy number 9: AC005476.1, SNORD56B, RN7SL683P.
- chr14:72,926,377–72,959,703, 1 gene, copy number 9 (within-gene range 4–9): DCAF4.
- chr14:72,960,595–73,274,640, 13 genes, copy number 9: AL442663.4, AL442663.1, ZFYVE1, RN7SL586P, AL442663.3, RBM25, AL442663.2, PSEN1, AC004858.1, PAPLN, AC004846.1, RNU6-419P, AC004846.2.

Autosomal genes at a single copy (total copy number 1): 50. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
